Somatic mutation profile of tumor specimen ALCH-B3XZ-TTP1-A (aliquot ALCH-B3XZ-TTP1-A-4-0-D-A799-36) from ALCHEMIST case ALCH-B3XZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,221 days).
Specimen ALCH-B3XZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) feb17a5b-7a32-44ed-82ea-660c3765ad56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3XZ-NB1-A (Blood Derived Normal), aliquot ALCH-B3XZ-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bae2b9d5-4200-48d1-bf6a-db606673a671

The open-access MAF lists 150 somatic variants for this specimen: 114 protein-altering or splice-affecting, 26 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 26, Nonsense Mutation 14, Intron 4, Splice Region 4, 3'UTR 3, RNA 2, 5'Flank 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.1929C>A p.C643* | Nonsense Mutation (SNP) | VAF 9/180 reads (5%) | catalogued as COSV99274394; called by muse, mutect2
- ADAMTS2 | c.1307C>G p.A436G | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51072328; called by muse, mutect2, varscan2
- ALG13 | c.1974C>T p.P658= | Splice Region (SNP) | VAF 12/147 reads (8%) | catalogued as COSV99321474; called by muse, mutect2
- CACNA1S | c.3286C>G p.R1096G | Missense Mutation (SNP) | VAF 54/483 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62938481; called by muse, mutect2, varscan2
- COL4A5 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 24/539 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM113171; called by muse, mutect2
- COL4A5 | c.3346G>T p.G1116* | Nonsense Mutation (SNP) | VAF 16/447 reads (4%) | catalogued as COSV60363460; called by muse, mutect2
- DLGAP3 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as rs929258984; called by muse, mutect2
- DPYSL3 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1561778293; called by muse, mutect2
- EFNB1 | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52662817; called by muse, mutect2
- FLVCR1 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV63134377; called by muse, mutect2
- GJA5 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.075); catalogued as rs782334563; called by muse, mutect2
- GRID2 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 28/636 reads (4%) | catalogued as COSV56175419; called by muse, mutect2
- GSTA5 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 20/504 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV52861603; called by muse, mutect2
- HDAC6 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100491355, COSV99043233; called by muse, mutect2
- KRTAP4-4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 24/603 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs1438318302; called by muse, mutect2
- MAGEC2 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as COSV55997721; called by muse, mutect2
- MAP1LC3C | c.114G>A p.P38= | Splice Region (SNP) | VAF 10/302 reads (3%) | catalogued as COSV100606529, COSV61804055; called by muse, mutect2
- MCCC2 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 32/492 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs767575019; ClinVar: uncertain significance; called by muse, mutect2
- MID1 | c.779C>G p.A260G | Missense Mutation (SNP) | VAF 13/335 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58195754; called by muse, mutect2
- MKRN3 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs375705600, CM1514567; called by muse, mutect2
- MUC16 | c.6349G>T p.A2117S | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV67465984; called by muse, mutect2
- MYO1E | c.2120G>T p.R707M | Missense Mutation (SNP) | VAF 17/299 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99896675; called by muse, mutect2
- NFASC | c.2045C>A p.P682H (on ENST00000339876 / NM_001378329.1; = p.P678H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100363397; called by muse, mutect2
- NSD1 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 19/305 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61784107, COSV61786943; called by muse, mutect2
- PCDH8 | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 48/504 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV58815332; called by muse, mutect2
- PCDHB10 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 18/560 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs782202174; called by muse, mutect2
- PCDHGA11 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.107); catalogued as COSV53951842; called by muse, mutect2, varscan2
- PGLYRP4 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as rs201083169; called by muse, mutect2, varscan2
- RHBDD3 | c.1159T>C p.*387Qext*14 | Nonstop Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as rs1463223858; called by muse, mutect2
- VCAN | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 44/936 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54095610; called by muse, mutect2
- ZNF256 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV99990880; called by muse, mutect2
- ZNF607 | c.704G>T p.S235I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.88); catalogued as COSV67696234; called by muse, mutect2
- AC231657.3 | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); called by muse, mutect2
- ACTG2 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM19 | c.2660C>G p.A887G | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2
- ADGRG3 | c.1161G>T p.W387C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD30A | c.407A>G p.D136G (on ENST00000611781; = p.D80G on NM_052997.2) | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2
- ARMCX4 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- ASPM | c.10093G>T p.G3365C | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ASPM | c.10092A>T p.K3364N | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BCAN | c.2561C>G p.P854R | Missense Mutation (SNP) | VAF 25/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BICD1 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.845); called by muse, mutect2
- BRWD3 | c.91-2A>T p.X31_splice | Splice Site (SNP) | VAF 18/588 reads (3%) | called by muse, mutect2
- CAMSAP2 | c.2581A>T p.K861* (on ENST00000236925 / NM_001297707.2; = p.K850* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- CAPN6 | c.1879C>T p.H627Y | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.052); called by muse, mutect2
- CARTPT | c.160A>T p.I54F | Missense Mutation (SNP) | VAF 41/646 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2
- CD163L1 | c.1088-7A>T | Splice Region (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CD1A | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 35/285 reads (12%) | called by muse, mutect2, varscan2
- CD79B | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 23/516 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2
- CEP120 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- CEP135 | c.608A>T p.D203V | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CHIT1 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CLRN2 | c.570G>T p.W190C | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPT1A | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 17/441 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CTNNA3 | c.1131C>A p.L377= | Splice Region (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- DBX2 | c.565A>T p.R189* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- DDX28 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- DGCR6L | c.459G>C p.Q153H | Missense Mutation (SNP) | VAF 15/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DIXDC1 | c.156T>A p.D52E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DMGDH | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 32/419 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2
- DNAH5 | c.8873G>T p.G2958V | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNMT3A | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- EBF3 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.745); called by muse, mutect2
- FAM83G | c.1242G>T p.W414C | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAT3 | c.13186C>A p.L4396M | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.944); called by muse, mutect2
- GOT2 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GRIPAP1 | c.1143G>T p.M381I | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- HROB | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- INSRR | c.2531G>T p.G844V | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRS4 | c.726G>T p.R242S | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- ITGAM | c.2999A>T p.H1000L (on ENST00000648685 / NM_001145808.2; = p.H999L on NM_000632.4) | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.013); called by muse, mutect2
- KCNA1 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM5C | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 29/406 reads (7%) | called by muse, mutect2
- KIAA1210 | c.304T>A p.C102S | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2
- LATS2 | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- LENG8 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); called by muse, mutect2
- LY6K | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); called by muse, mutect2
- MAGED1 | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 16/553 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.552); called by muse, mutect2
- MKRN3 | c.1033C>A p.R345S | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH4 | c.3940C>A p.Q1314K | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2
- NOTCH2 | c.7249C>G p.P2417A | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OPN4 | c.512T>A p.V171E | Missense Mutation (SNP) | VAF 13/398 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR4E2 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- OR4K13 | c.116T>G p.V39G | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- PCDHB9 | c.2041G>T p.A681S | Missense Mutation (SNP) | VAF 39/562 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.22); called by muse, mutect2
- PDGFRA | c.930T>A p.H310Q | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.759); called by muse, mutect2
- PIK3C2B | c.3437G>C p.G1146A | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLR3A | c.3097G>C p.V1033L | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM10 | c.1979G>C p.R660P | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- RCOR3 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, mutect2
- ROR1 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2
- RTN4R | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- RUNDC1 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 10/229 reads (4%) | called by muse, mutect2
- SEMA5A | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.149); called by muse, mutect2
- SHROOM4 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 22/556 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLITRK1 | c.1967C>A p.S656Y | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2
- SLX4 | c.4543G>T p.D1515Y | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SON | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- SRRD | c.932G>A p.W311* | Nonsense Mutation (SNP) | VAF 11/258 reads (4%) | called by muse, mutect2
- TBC1D13 | c.330G>C p.W110C | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TGIF2LX | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 44/740 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- TKTL1 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2
- TMEM117 | c.161T>A p.V54D | Missense Mutation (SNP) | VAF 17/365 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2
- TMPRSS5 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- TNS3 | c.4021G>T p.E1341* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- TRAV14DV4 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- TRIM24 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 12/243 reads (5%) | called by muse, mutect2
- VCAN | c.667G>T p.G223* | Nonsense Mutation (SNP) | VAF 44/940 reads (5%) | called by muse, mutect2
- WT1 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 18/562 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.874); called by muse, mutect2
- XK | c.922A>T p.I308F | Missense Mutation (SNP) | VAF 43/672 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZG16B | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2
- ZNF219 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- ZNF219 | c.1015G>T p.G339W | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2
- ZNF592 | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 27/394 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.073); called by muse, mutect2
- ACHE | c.876C>A p.G292= | Silent (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- ACKR1 | c.576T>A p.G192= | Silent (SNP) | VAF 13/221 reads (6%) | called by muse, mutect2
- BMPR1B | c.87C>A p.V29= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- CAMSAP2 | c.3729A>G p.K1243= (on ENST00000236925 / NM_001297707.2; = p.K1232= on NM_203459.3) | Silent (SNP) | VAF 23/228 reads (10%) | catalogued as rs773232712; called by muse, mutect2
- CELSR1 | c.684G>A p.G228= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- CHRNB2 | c.831G>T p.T277= | Silent (SNP) | VAF 11/268 reads (4%) | catalogued as COSV63808489; called by muse, mutect2
- CUBN | c.6012G>T p.V2004= | Silent (SNP) | VAF 14/276 reads (5%) | catalogued as COSV100912706; called by muse, mutect2
- DIS3L | c.1839G>A p.L613= (on ENST00000319212 / NM_001143688.3; = p.L530= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- DST | c.19533A>T p.V6511= (on ENST00000361203 / NM_001374722.1; = p.V4208= on NM_015548.5) | Silent (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
- KCND2 | c.690C>T p.F230= | Silent (SNP) | VAF 24/490 reads (5%) | catalogued as COSV58579682, COSV58610603; called by muse, mutect2
- KCNH7 | c.3006C>A p.P1002= | Silent (SNP) | VAF 14/277 reads (5%) | called by muse, mutect2
- MAGED1 | c.1290C>A p.P430= | Silent (SNP) | VAF 16/549 reads (3%) | called by muse, mutect2
- MAGEE1 | c.741C>T p.P247= | Silent (SNP) | VAF 28/251 reads (11%) | called by muse, mutect2, varscan2
- NAV2 | c.4200C>T p.A1400= (on ENST00000396087 / NM_001244963.2; = p.A1377= on NM_145117.5) | Silent (SNP) | VAF 24/486 reads (5%) | called by muse, mutect2
- NR0B1 | c.1035G>T p.P345= | Silent (SNP) | VAF 18/379 reads (5%) | catalogued as COSV100973549, COSV66764143; called by muse, mutect2
- OR2T35 | c.897A>C p.A299= | Silent (SNP) | VAF 30/348 reads (9%) | called by muse, mutect2, varscan2
- OR6P1 | c.261C>A p.T87= | Silent (SNP) | VAF 55/555 reads (10%) | catalogued as COSV58108099; called by muse, mutect2
- OR6Y1 | c.963G>A p.G321= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- PNCK | c.156G>T p.R52= (on ENST00000340888 / NM_001366975.1; = p.R135= on NM_001039582.3) | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- PTPRT | c.510G>A p.L170= | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- SLITRK1 | c.1455C>A p.S485= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as COSV65676383; called by muse, mutect2
- TBX22 | c.1074C>A p.P358= | Silent (SNP) | VAF 19/446 reads (4%) | catalogued as COSV64786730; called by muse, mutect2
- USP6 | c.1281G>T p.V427= | Silent (SNP) | VAF 21/719 reads (3%) | called by muse, mutect2
- ZFP92 | c.948C>T p.G316= | Silent (SNP) | VAF 13/210 reads (6%) | catalogued as rs1556975087, COSV100100295; called by muse, mutect2
- ZMYM3 | c.1422C>A p.G474= | Silent (SNP) | VAF 16/345 reads (5%) | called by muse, mutect2
- ZNF831 | c.2670T>G p.A890= | Silent (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- ADGRA1 | chr10:133084885 G>A | 5'Flank (SNP) | VAF 12/278 reads (4%) | catalogued as rs1564840096, COSV63416610, COSV63416646; called by muse, mutect2
- ADGRB3 | c.2481-673G>T | Intron (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- CLRN1 | c.*1118G>T | 3'UTR (SNP) | VAF 20/624 reads (3%) | called by muse, mutect2
- COX6A1P2 | n.162G>T | RNA (SNP) | VAF 22/726 reads (3%) | called by muse, mutect2
- DENND1B | c.83-20648G>T | Intron (SNP) | VAF 15/427 reads (4%) | catalogued as COSV99343738; called by muse, mutect2
- PSG2 | c.*37G>T | 3'UTR (SNP) | VAF 8/179 reads (4%) | called by muse, mutect2
- SLC12A1 | c.1215+65G>T | Intron (SNP) | VAF 26/328 reads (8%) | catalogued as COSV100372497; called by muse, mutect2
- SSPOP | n.9609A>T | RNA (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- SULF1 | c.*525C>A | 3'UTR (SNP) | VAF 12/229 reads (5%) | catalogued as COSV52695568; called by muse, mutect2
- ZAP70 | c.889+25G>C | Intron (SNP) | VAF 15/162 reads (9%) | catalogued as rs201824457; called by muse, mutect2
